Gene-level copy-number profile of tumor specimen TCGA-EE-A20C-06A from TCGA case TCGA-EE-A20C, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 71.5 years (26,129 days).
Specimen TCGA-EE-A20C-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.d4a3f1f8-9013-49e5-801c-e32608ea5036.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A20C-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bf4ed708-1bc6-4dda-bd05-6a502da54233

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 65; copy number 1: 948; copy number 2: 4,459; copy number 3: 19,784; copy number 4: 33,236; copy number 5: 507; copy number 6: 807; copy number 9: 2; copy number 10: 1; copy number 12: 6; copy number 14: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A20C-06A-11D-A194-01): tumor purity 0.93, ploidy 3.55, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 65 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–4,994,972, 65 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 11 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:195,003,711–195,026,370, 1 gene, copy number 14 (within-gene range 3–14): AC010983.1.
- chr6:81,724,722–81,736,353, 1 gene, copy number 14 (within-gene range 4–14): AL078599.2.
- chr7:62,275,361–62,275,678, 1 gene, copy number 10: AC128676.1.
- chr8:131,712,512–131,712,980, 1 gene, copy number 9: AC060788.1.
- chr11:48,880,111–48,961,810, 6 genes, copy number 12: AC027369.6, AC027369.3, AC027369.4, AC027369.5, TRIM51CP, AC027369.2.
- chr12:91,050,491–91,058,024, 1 gene, copy number 9: KERA.

Autosomal genes at a single copy (total copy number 1): 948. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
